Somatic mutation profile of tumor specimen TARGET-10-PARGKD-09A (aliquot TARGET-10-PARGKD-09A-01D) from TARGET case TARGET-10-PARGKD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,521 days).
Specimen TARGET-10-PARGKD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb2b847e-1e27-4f6d-bf02-7263496099db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARGKD-10A (Blood Derived Normal), aliquot TARGET-10-PARGKD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/700d2f5d-54ea-4814-9e4f-43bd1b90425a

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, 5'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ2B | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765674376; called by muse, mutect2, varscan2
- MTTP | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs761103347, COSV99645030; called by muse, mutect2, varscan2
- PEG3 | c.2219C>A p.P740H | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55639517; called by muse, mutect2, varscan2
- BBS4 | c.1339C>T p.H447Y | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CADPS | c.3491C>T p.S1164L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- FABP9 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- IGHV2-26 | c.355_356delinsGGGG p.I119Gfs*? | Frame Shift Ins (INS) | VAF 23/46 reads (50%) | called by pindel, varscan2*
- ISY1-RAB43 | c.917T>G p.V306G | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3CB | c.1360A>G p.T454A | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CXCL6 | c.130C>T p.L44= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as rs1274153245; called by muse, mutect2, varscan2
- PDE10A | c.465C>T p.I155= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV63096244; called by muse, mutect2, varscan2
- TMEM121B | chr22:17122637 ins GGGGAG | 5'Flank (INS) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- TMEM121B | chr22:17122639 T>GGGAGGA | 5'Flank (INS) | VAF 14/30 reads (47%) | called by mutect2*, pindel, varscan2*
